Surgical pathology report (de-identified scan), TCGA case TCGA-49-4510, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4510-01A (Primary Tumor).

FINAL DIAGNOSIS -----

. R4 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

. STATION 7 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

. LUNG, LEFT UPPER LOBE (LOBECTOMY): INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (5 CM). THE TUMOR HAS FEATURES OF PAPILLARY ADENOCARCINOMA OF THE LUNG (AS DESCRIBED BY SILVER AND SKIN), AND IS ASSOCIATED WITH A PERIPHERAL BRONCHIOLOALVEOLAR COMPONENT. THE CARCINOMA ABUTS BUT DOES NOT INVOLVE THE PLEURA. ALL MARGINS INCLUDING BRONCHIAL AND VASCULAR MARGINS ARE NEGATIVE FOR TUMOR. FOCAL VASCULAR INVASION IS SEEN. SURROUNDING LUNG SHOWS TYPICAL PNEUMOCYTE HYPERPLASIA. METASTATIC CARCINOMA IN ONE (1) OF

Source: NCI Genomic Data Commons file 05107a0f-9a14-4303-bcec-179507a40bc4 (TCGA-49-4510.DE27239D-52AE-4979-979F-51E1CE7A43E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).